Gene-level copy-number profile of tumor specimen TCGA-XE-AAOL-01A from TCGA case TCGA-XE-AAOL, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 39.0 years (14,230 days).
Specimen TCGA-XE-AAOL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-TGCT.995ff6b5-781f-4542-ab69-eb17c532e4d1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-XE-AAOL-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 811 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a458619d-c943-4dbb-a8a8-e75469fef09b

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1; copy number 2: 3,514; copy number 3: 11,313; copy number 4: 17,818; copy number 5: 10,615; copy number 6: 8,529; copy number 7: 1,592; copy number 8: 3,225; copy number 9: 1,696; copy number 10: 429; copy number 11: 71; copy number 12: 289; copy number 13: 342; copy number 14: 146; copy number 15: 197; copy number 16: 33; copy number 24: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-XE-AAOL-01A-11D-A434-01): tumor purity 0.73, ploidy 4.8, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 3,205 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,588,772–58,565,212, 130 genes, copy number 12–24 (broad region; genes not listed).
- chr8:41,032,892–145,066,685, 1,615 genes, copy number 9–15 (broad region; genes not listed).
- chr12:66,767–40,369,285, 884 genes, copy number 10–16 (broad region; genes not listed).
- chr12:75,926,213–85,882,992, 108 genes, copy number 9–11 (broad region; genes not listed).
- chr12:85,958,686–86,016,441, 2 genes, copy number 9: AC016993.1, AC139697.1.
- chr13:48,975,912–56,216,942, 128 genes, copy number 10 (broad region; genes not listed).
- chr21:36,966,461–46,665,124, 291 genes, copy number 9 (within-gene range 7–9) (broad region; genes not listed).
- chr22:25,959,074–27,460,060, 47 genes, copy number 10: Z98949.2, RN7SKP169, Z98949.1, LINC02559, AL022337.1, SEZ6L, SEZ6L-AS1, RNA5SP495, Z99714.1, ASPHD2, HPS4, SRRD, TFIP11, Z95115.1, TPST2, MIR548J, HMGB1P10, Z95115.2, CRYBB1, CRYBA4, ISCA2P1, MIAT, Z99774.5, Z99774.1, Z99774.4, Z99774.2, MIATNB, Z99774.3, LINC01422, Z97353.1, Z97353.2, AL008638.3, RNU6-1066P, AL008638.5, AL008638.4, AL008638.2, AL008638.6, AL008638.1, AL021153.1, LINC01638, AL020994.3, AL020994.1, LINC02554, AL020994.2, AL049536.1, AL050402.2, AL050402.1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
